Gene-level copy-number profile of tumor specimen TCGA-G3-A25S-01A from TCGA case TCGA-G3-A25S, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.5 years (23,571 days).
Specimen TCGA-G3-A25S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.bffb556b-2d9e-4433-b71e-25a1584a9d63.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G3-A25S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/239caa2e-42d1-4226-9d96-1e108203c3ca

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 952; copy number 2: 13,375; copy number 3: 15,154; copy number 4: 17,974; copy number 5: 3,293; copy number 6: 5,782; copy number 7: 1,854; copy number 8: 956; copy number 9: 100; copy number 10: 96; copy number 11: 94; copy number 13: 120; copy number 14: 3; copy number 16: 13; copy number 17: 25; copy number 18: 4; copy number 21: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G3-A25S-01A-11D-A16U-01): tumor purity 0.67, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:61,034,636–61,135,969, 4 genes: AC005884.1, AC005884.2, RPL23AP74, AC005856.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 461 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:107,140,007–107,505,448, 2 genes, copy number 11 (within-gene range 3–11): NTNG1, NDUFA4P1.
- chr1:110,519,837–110,674,940, 3 genes, copy number 14 (within-gene range 4–14): KCNA2, AL365361.1, KCNA3.
- chr1:237,862,175–241,595,642, 58 genes, copy number 9 (within-gene range 7–9): AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123, AL592076.1, AL359764.1, AL359764.2, AL359764.3, FH, KMO.
- chr11:56,775,261–57,515,780, 28 genes, copy number 13: OR5G1P, OR5G4P, OR5G5P, OR5G3, LINC02735, FADS2B, OR5AK3P, OR5AK2, OR5AK1P, OR5BQ1P, OR5AK4P, OR5AO1P, OR5BP1P, LRRC55, APLNR, TNKS1BP1, AP000781.1, SSRP1, P2RX3, PRG3, PRG2, AP000781.2, SLC43A3, RNA5SP341, RN7SKP259, RTN4RL2, AP002893.1, SLC43A1.
- chr11:69,048,932–69,704,022, 18 genes, copy number 13–21: TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19.
- chr11:74,171,267–74,485,742, 11 genes, copy number 9 (within-gene range 2–9): PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL.
- chr11:77,128,246–77,994,671, 21 genes, copy number 9 (within-gene range 3–9): MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4.
- chr16:46,469,341–50,121,943, 96 genes, copy number 10 (broad region; genes not listed).
- chr17:47,807,372–49,900,893, 117 genes, copy number 11–17 (broad region; genes not listed).
- chr17:50,367,857–50,849,270, 32 genes, copy number 13: MRPL27, EME1, LRRC59, Y_RNA, AC004707.1, ACSF2, MRPS21P9, CHAD, AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33.
- chr17:52,862,121–53,106,358, 3 genes, copy number 18: LINC02089, LINC02876, MTCO1P40.
- chr17:53,353,427–53,354,134, 1 gene, copy number 18: AC005341.1.
- chr17:54,477,796–56,511,659, 23 genes, copy number 9–16 (within-gene range 7–16): ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1.
- chr17:82,214,227–83,095,122, 48 genes, copy number 13 (within-gene range 7–13): AC132872.2, SLC16A3, MIR6787, CSNK1D, AC132872.3, AC132872.4, AC132872.5, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.6, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1, TBCD, AC068014.1, ZNF750, AC087222.1, B3GNTL1, AC130371.1, METRNL.

Autosomal genes at a single copy (total copy number 1): 952. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
